Somatic mutation profile of tumor specimen 0DQWRN from CCDI case PBCFRH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.3 years (3,030 days).
Specimen 0DQWRN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae581208-6135-441e-bd16-40ddcf6d0b7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQWS4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b002eb1a-db7b-4609-8e94-6337aba4f5a3

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR5F1 | c.921G>T p.R307S | Missense Mutation (SNP) | VAF 281/1330 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.214); catalogued as COSV53545131; called by muse, mutect2, varscan2
- CREBBP | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 66/1104 reads (6%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); called by muse, mutect2
- CYP4F12 | c.1386C>A p.S462= | Silent (SNP) | VAF 320/692 reads (46%) | catalogued as COSV100216018; called by muse, mutect2, varscan2
- CRTC3 | c.578-14T>C | Intron (SNP) | VAF 245/442 reads (55%) | called by muse, mutect2, varscan2
